Gene-level copy-number profile of tumor specimen C3L-02358-03 from CPTAC case C3L-02358, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 75.8 years (27,672 days).
Specimen C3L-02358-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6b150b12-c444-4681-a2f7-303e0ad487b1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02358-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/89771203-642b-48e7-ac5b-86c36431151c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 16; copy number 2: 3,893; copy number 3: 12,423; copy number 4: 12,841; copy number 5: 9,552; copy number 6: 12,287; copy number 7: 2,244; copy number 8: 1,281; copy number 9: 631; copy number 10: 1,235; copy number 11: 93; copy number 12: 87; copy number 13: 127; copy number 14: 1,449; copy number 15: 38; copy number 17: 168; copy number 20: 7; copy number 23: 11.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:257,864–359,681, 2 genes (within-gene range 0–9): AP006222.1, AP006222.2.
- chr13:80,619,098–80,620,067, 1 gene: HNRNPA1P31.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,846 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:89,295–133,723, 1 gene, copy number 9 (within-gene range 2–9): AL627309.1.
- chr1:131,025–195,411, 10 genes, copy number 9: CICP27, AL627309.6, AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2.
- chr1:38,193,619–42,846,422, 133 genes, copy number 9–11 (within-gene range 6–11) (broad region; genes not listed).
- chr4:49,579,833–49,589,529, 2 genes, copy number 9: AC119751.4, SNX18P25.
- chr5:18,958,147–41,510,628, 272 genes, copy number 9–10 (broad region; genes not listed).
- chr5:44,698,431–45,895,970, 11 genes, copy number 9–14: AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr7:37,032–1,747,954, 52 genes, copy number 9–11: AC215522.1, AC093627.1, AC093627.6, AC093627.5, AC093627.4, AC093627.7, AC093627.2, AC093627.3, FAM20C, AC145676.1, FOXL3, AC226118.1, AC147651.1, PDGFA, HRAT92, PRKAR1B, PRKAR1B-AS2, PRKAR1B-AS1, DNAAF5, SUN1, GET4, AC073957.3, ADAP1, COX19, CYP2W1, C7orf50, MIR339, AC073957.1, GPR146, AC073957.2, AC091729.1, AC091729.2, GPER1, ZFAND2A, ZFAND2A-DT, UNCX, AC073094.1, MICALL2, AC102953.1, AC102953.2, INTS1, AC093734.1, MAFK, TMEM184A, PSMG3, PSMG3-AS1, TFAMP1, AC074389.2, ELFN1, AC074389.3, AC074389.1, ELFN1-AS1.
- chr7:1,838,586–1,849,931, 2 genes, copy number 9 (within-gene range 5–9): AC104129.1, MIR4655.
- chr7:38,239,580–38,378,804, 24 genes, copy number 9 (within-gene range 5–9): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRG-AS1, TRGV5P, TRGV5, TRGV4, TRGV3, TRGV2, TRGV1.
- chr7:74,773,962–75,738,962, 37 genes, copy number 10: NCF1, GTF2IRD2, STAG3L2, PMS2P5, Y_RNA, SPDYE12P, CASTOR2, RCC1L, Metazoa_SRP, GTF2IRD2B, NCF1C, GTF2IP1, PHBP6, AC211486.5, AC211486.2, AC211486.4, SPDYE13, PMS2P10, Y_RNA, SPDYE14, AC211486.3, Y_RNA, SPDYE15, PMS2P2, Y_RNA, STAG3L1, Y_RNA, AC211486.1, TRIM73, NSUN5P1, POM121C, AC211429.1, SPDYE5, PMS2P3, Y_RNA, HIP1, AC004491.1.
- chr7:79,452,877–88,306,894, 74 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr7:90,245,174–91,556,848, 19 genes, copy number 9–13: CFAP69, Y_RNA, AC002064.2, AC002064.1, FAM237B, GTPBP10, AC002064.3, CLDN12, AC006153.1, CDK14, AC002456.2, AC002456.1, TVP23CP1, AC002458.1, PTP4A1P3, FZD1, AC079760.2, NIPA2P1, AC079760.1.
- chr7:92,412,550–93,574,730, 22 genes, copy number 9–13: TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1, RN7SL7P, SAMD9, SAMD9L, HEPACAM2, VPS50, CALCR, MIR653, MIR489.
- chr7:96,858,182–97,014,088, 6 genes, copy number 14 (within-gene range 8–14): MARK2P10, RN7SL252P, DLX6-AS1, AC004774.1, AC004774.3, DLX6.
- chr7:98,106,862–109,764,357, 308 genes, copy number 10–23 (broad region; genes not listed).
- chr7:149,126,416–150,076,655, 29 genes, copy number 9–12: ZNF398, AC004890.1, ZNF282, ZNF212, ZNF783, AC004890.3, AC004890.2, AC004941.2, NPM1P12, AC004941.1, AC073314.1, ZNF777, ZNF746, ZNF767P, KRBA1, ZNF467, SSPOP, ZNF862, AC004877.2, AC004877.1, ATP6V0E2-AS1, ATP6V0E2, AC093458.1, AC093458.2, AC092681.3, AC092681.1, AC092681.2, AC092666.1, AC092666.2.
- chr8:7,295,014–7,298,024, 1 gene, copy number 9: FAM90A20P.
- chr8:40,519,565–46,028,892, 83 genes, copy number 12–13 (broad region; genes not listed).
- chr8:48,913,916–49,741,321, 10 genes, copy number 14: AC013701.1, SNAI2, AC044893.2, PPDPFL, AC044893.1, RN7SKP294, RFPL4AP7, AC090155.2, AC090155.1, PSAT1P1.
- chr8:49,909,789–145,066,685, 1,427 genes, copy number 14 (broad region; genes not listed).
- chr9:63,581,254–63,859,641, 13 genes, copy number 10: AL591438.1, AL591438.2, CDRT15P7, AL772155.1, AL772155.2, MYO5BP3, CDK2AP2P3, PTGER4P3, CR786580.1, RNA5SP284, DUX4L50, MIR4477B, FRG1JP.
- chr10:133,657,235–133,778,699, 17 genes, copy number 9: CLUHP5, DUX4L28, DUX4L25, DUX4L24, DUX4L23, DUX4L22, DUX4L21, DUX4L20, DUX4L29, DUX4L10, DUX4L11, DUX4L12, DUX4L13, DUX4L14, DUX4L15, RPL23AP60, BX322534.1.
- chr16:34,941,977–34,943,880, 1 gene, copy number 10: AC135776.4.
- chr16:35,169,692–35,575,494, 39 genes, copy number 9: UBE2MP1, SLC25A1P4, AC023824.1, AC023824.2, AC023824.4, AC023824.3, TP53TG3GP, RARRES2P5, FGFR3P5, FRG2JP, RARRES2P6, AGGF1P8, FRG2HP, RARRES2P9, AGGF1P9, C2orf69P4, LINC01566, FRG2GP, AGGF1P4, FRG2IP, RARRES2P7, AGGF1P5, C2orf69P3, AC018558.4, ZNF971P, FRG2DP, RARRES2P10, AGGF1P6, AC018558.2, C2orf69P2, AC018558.3, AC018558.7, AC018558.1, TP53TG3HP, AC018558.5, RARRES2P8, AGGF1P7, C2orf69P1, C1QL1P1.
- chr16:35,879,036–35,912,516, 3 genes, copy number 9: AC116553.1, AC116553.2, PPP1R1AP2.
- chr17:15,105,237–17,677,688, 126 genes, copy number 10 (broad region; genes not listed).
- chr17:18,172,625–19,214,045, 78 genes, copy number 10–15 (within-gene range 7–15) (broad region; genes not listed).
- chr17:74,043,452–75,500,452, 71 genes, copy number 10 (within-gene range 7–10) (broad region; genes not listed).
- chr19:16,574,907–16,660,115, 2 genes, copy number 10 (within-gene range 5–10): MED26, AC008764.4.
- chr19:16,610,374–19,663,676, 162 genes, copy number 10 (within-gene range 5–10) (broad region; genes not listed).
- chr20:87,250–30,214,976, 532 genes, copy number 10 (broad region; genes not listed).
- chr20:31,257,664–34,540,748, 122 genes, copy number 9–13 (within-gene range 4–13) (broad region; genes not listed).
- chr20:41,991,140–47,188,844, 157 genes, copy number 9–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 16. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
